Somatic mutation profile of tumor specimen TCGA-KL-8326-01A (aliquot TCGA-KL-8326-01A-11D-2310-10) from TCGA case TCGA-KL-8326, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 69.2 years (25,267 days).
Specimen TCGA-KL-8326-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba53c171-45ac-4e23-b942-b40fe68aa1d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8326-11A (Solid Tissue Normal), aliquot TCGA-KL-8326-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f6f6df2-e53e-4809-bb86-c07e314c284d

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 3, 3'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUBN | c.8492G>A p.C2831Y | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100913380; called by muse, mutect2
- ECEL1 | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100458932; called by muse, mutect2
- KIAA1755 | c.1292C>A p.A431E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV99642561; called by muse, mutect2, varscan2
- KMT2C | c.11645C>T p.T3882I | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV51438617; called by muse, mutect2
- NR4A1 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs1368531985, COSV99671629; called by muse, mutect2
- PJA1 | c.854A>T p.H285L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV100824790, COSV64053726; called by muse, mutect2
- TESMIN | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs775340621, COSV54832149; called by muse, mutect2, varscan2
- CREG2 | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.959); called by muse, mutect2
- CREG2 | c.582G>T p.M194I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- DYNC2H1 | c.10815C>A p.D3605E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GIPC3 | c.790A>T p.K264* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- ILKAP | c.795T>G p.Y265* | Nonsense Mutation (SNP) | VAF 17/267 reads (6%) | called by muse, mutect2
- REV1 | c.1706G>A p.C569Y | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STXBP5 | c.1814C>A p.S605* | Nonsense Mutation (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2, varscan2
- TSC1 | c.520_532del p.E174Sfs*32 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- TYMP | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CXorf66 | c.267C>T p.A89= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100983929; called by muse, mutect2, varscan2
- DUSP21 | c.150C>T p.A50= | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as COSV100173532, COSV100173656; called by muse, mutect2, varscan2
- JAG1 | c.2103C>A p.T701= | Silent (SNP) | VAF 11/141 reads (8%) | catalogued as CD994168; called by muse, mutect2
- MAPKAP1 | c.1072A>C p.R358= (on ENST00000265960 / NM_001006617.3; = p.R322= on NM_024117.3) | Silent (SNP) | VAF 74/174 reads (43%) | called by muse, mutect2, varscan2
- RFX7 | c.1590T>A p.A530= (on ENST00000559447 / NM_001368074.1; = p.A627= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100429241; called by muse, mutect2
- ZBTB16 | c.273G>T p.T91= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV100252004; called by muse, mutect2
- CCDC185 | c.*97A>G | 3'UTR (SNP) | VAF 71/190 reads (37%) | catalogued as COSV100838798, COSV100838830; called by muse, mutect2, varscan2
- NPY2R | c.*986G>C | 3'UTR (SNP) | VAF 11/119 reads (9%) | catalogued as COSV100279869; called by muse, mutect2
